Somatic mutation profile of tumor specimen 0DUB86 from CCDI case PBCKEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.5 years (6,018 days).
Specimen 0DUB86: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 106c1fba-33e9-4800-976b-12648478e23b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB67 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03c32021-e0de-4e56-a506-c9abbc752c83

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Intron 3, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC1 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 87/455 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280637039, COSV57319692; called by muse, mutect2, varscan2
- CPAMD8 | c.3964G>A p.V1322M (on ENST00000651564; = p.V1275M on NM_015692.5) | Missense Mutation (SNP) | VAF 137/504 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781277253, COSV101488549; called by muse, mutect2, varscan2
- DSCAM | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 134/630 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs201979167; called by muse, mutect2, varscan2
- GIGYF1 | c.2995G>A p.G999R | Missense Mutation (SNP) | VAF 220/1061 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs778027077, COSV51940625; called by muse, mutect2, varscan2
- KCNV1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 172/780 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99819263, COSV99819543; called by muse, mutect2, varscan2
- LCE4A | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.414); catalogued as COSV59266683; called by muse, mutect2
- LMO2 | c.305G>A p.R102H (on ENST00000395833 / NM_001142315.2; = p.R171H on NM_005574.4) | Missense Mutation (SNP) | VAF 111/769 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1401579360, COSV57645438; called by muse, mutect2, varscan2
- NAV3 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 125/583 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs776928962, COSV57097401; called by muse, mutect2, varscan2
- NTSR2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 78/608 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs752482430, COSV60991850, COSV60993127; called by muse, mutect2, varscan2
- PRMT8 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 170/340 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs756205618; called by muse, mutect2, varscan2
- PTPRN2 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 99/831 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369875860, COSV101235371; called by muse, mutect2, varscan2
- SLC15A1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 148/365 reads (41%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.955); catalogued as rs1782674, COSV64729977; called by muse, mutect2, varscan2
- TP53BP1 | c.5531G>A p.R1844H | Missense Mutation (SNP) | VAF 41/577 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756730049, COSV99538594; called by muse, mutect2
- UBE3C | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 35/1333 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100780153, COSV61953140; called by muse, mutect2
- WDR11 | c.1774C>A p.L592M | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54787172; called by muse, mutect2, varscan2
- WWP1 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 109/1122 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs778649126; called by muse, mutect2
- ADAM28 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 91/1187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AFAP1L1 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 253/581 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP5 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 87/703 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCHE | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 52/750 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- BMP15 | c.1147G>C p.G383R | Missense Mutation (SNP) | VAF 290/353 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DNAJB6 | c.928_930del p.Q310del | In Frame Del (DEL) | VAF 139/794 reads (18%) | called by mutect2, pindel, varscan2
- FIGN | c.1237T>A p.S413T | Missense Mutation (SNP) | VAF 161/507 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FLG2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.406); called by muse, mutect2
- GFPT1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 49/880 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HPSE | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ITGA6 | c.2378T>C p.V793A (on ENST00000442250; = p.V754A on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/878 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KMT2D | c.15551_15557del p.V5184Afs*57 | Frame Shift Del (DEL) | VAF 118/391 reads (30%) | called by mutect2, pindel, varscan2
- KMT2D | c.5779_5782+1del p.X1927_splice | Splice Site (DEL) | VAF 156/421 reads (37%) | called by mutect2, pindel, varscan2
- KNG1 | c.1164C>A p.F388L | Missense Mutation (SNP) | VAF 104/616 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MET | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 46/1212 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- MGAM | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 227/1050 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 153/710 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.38481T>C p.T12827= | Splice Region (SNP) | VAF 60/606 reads (10%) | called by muse, mutect2
- MYRFL | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 21/405 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.033); called by muse, mutect2
- NOTCH2 | c.6781G>T p.E2261* | Nonsense Mutation (SNP) | VAF 194/508 reads (38%) | called by muse, mutect2, varscan2
- NPHP4 | c.1316A>T p.E439V | Missense Mutation (SNP) | VAF 112/630 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NRXN1 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2
- PASD1 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PLD4 | c.180G>C p.W60C | Missense Mutation (SNP) | VAF 78/462 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG5 | c.2717G>T p.C906F (on ENST00000400915 / NM_001042663.3; = p.C869F on NM_020631.6) | Missense Mutation (SNP) | VAF 115/315 reads (37%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TAS2R4 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 38/1127 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TCF7 | c.356_360dup p.V121Rfs*80 | Frame Shift Ins (INS) | VAF 115/342 reads (34%) | called by pindel, varscan2
- TMEM268 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 134/365 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WBP4 | c.654T>A p.D218E | Missense Mutation (SNP) | VAF 25/593 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AHSP | c.234C>A p.A78= | Silent (SNP) | VAF 62/326 reads (19%) | called by muse, mutect2, varscan2
- ASB1 | c.768G>T p.L256= | Silent (SNP) | VAF 247/829 reads (30%) | called by muse, mutect2, varscan2
- FAM13C | c.1041G>T p.L347= | Silent (SNP) | VAF 83/373 reads (22%) | catalogued as rs763827338; called by muse, mutect2, varscan2
- KCNK9 | c.912G>A p.S304= | Silent (SNP) | VAF 103/948 reads (11%) | catalogued as rs201403581; called by muse, mutect2, varscan2
- NT5DC2 | c.1215G>C p.T405= | Silent (SNP) | VAF 226/585 reads (39%) | called by muse, mutect2, varscan2
- PRND | c.30G>T p.L10= | Silent (SNP) | VAF 219/761 reads (29%) | called by muse, mutect2, varscan2
- SDS | c.915C>A p.G305= | Silent (SNP) | VAF 67/352 reads (19%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 28/854 reads (3%) | called by muse, mutect2
- SPANXN1 | c.108C>T p.P36= | Silent (SNP) | VAF 332/414 reads (80%) | catalogued as rs782331742, COSV100979327, COSV65122143; called by muse, mutect2, varscan2
- SPRY4 | c.360G>A p.V120= (on ENST00000434127 / NM_001127496.3; = p.V143= on NM_030964.4) | Silent (SNP) | VAF 152/381 reads (40%) | catalogued as rs780206920; called by muse, mutect2, varscan2
- TTN | c.50901C>A p.G16967= (on ENST00000591111; = p.G9543= on NM_003319.4) | Silent (SNP) | VAF 45/898 reads (5%) | called by muse, mutect2
- ZNF844 | c.963C>A p.P321= | Silent (SNP) | VAF 66/505 reads (13%) | called by muse, mutect2, varscan2
- EVC2 | c.-11C>G | 5'UTR (SNP) | VAF 21/211 reads (10%) | catalogued as rs919012519; called by muse, mutect2, varscan2
- NCF1 | c.800+55C>T | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as rs587619899; called by mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55814242; called by muse, mutect2
- TBX10 | c.*31C>T | 3'UTR (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 18/506 reads (4%) | called by muse, mutect2
